Somatic mutation profile of tumor specimen TARGET-10-PASHUP-09A (aliquot TARGET-10-PASHUP-09A-01D) from TARGET case TARGET-10-PASHUP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,534 days).
Specimen TARGET-10-PASHUP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af219963-e467-4c33-b469-c77e4cff5043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASHUP-14A (Bone Marrow Normal), aliquot TARGET-10-PASHUP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62c61cfe-dd49-4c1e-b3d9-f9a4bd152b37

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 3, Silent 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD3B2 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 58/110 reads (53%) | catalogued as rs148200568, CM081308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH16A1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs764442560, COSV53196857; called by muse, varscan2
- CDK5RAP3 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV58116224; called by muse, mutect2, varscan2
- COL4A3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as COSV67420622; called by muse, mutect2, varscan2
- DCHS1 | c.6832C>T p.P2278S | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs749651000, COSV55043115; called by muse, mutect2, varscan2
- NRF1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1205251935, COSV56210413; called by muse, mutect2, varscan2
- OTOP3 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV60913414, COSV60915117; called by muse, mutect2, varscan2
- RALGPS1 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52233418; called by muse, mutect2, varscan2
- RPL5 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV59872919; called by muse, mutect2, varscan2
- RYR2 | c.5263A>C p.T1755P | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV63715380; called by muse, mutect2, varscan2
- SLC17A8 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as rs747411001, COSV60126852; called by muse, mutect2, varscan2
- STAB1 | c.6065G>A p.R2022H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs774412437, COSV58743373; called by muse, mutect2, varscan2
- TEX13A | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as COSV61153346, COSV61184135; called by muse, mutect2, varscan2
- TMEM106C | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 40/120 reads (33%) | catalogued as rs1188114118, COSV56743629; called by muse, mutect2, varscan2
- OR2J1 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2
- XIRP1 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- NPHS1 | c.2469G>A p.A823= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs371646734; ClinVar: uncertain significance; called by mutect2, varscan2
- PYHIN1 | c.465C>T p.S155= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as COSV63724479; called by muse, mutect2, varscan2
- WDFY3 | c.3547C>A p.R1183= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as COSV55694712; called by muse, mutect2
- ARL1 | c.*43C>G | 3'UTR (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- ATRIP | c.247+97C>T | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- PLRG1 | c.313+107A>G | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
